Somatic mutation profile of tumor specimen TARGET-30-PALHVD-01A (aliquot TARGET-30-PALHVD-01A-01W) from TARGET case TARGET-30-PALHVD, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Medulla of adrenal gland; Age at diagnosis: 4.5 years (1,634 days).
Specimen TARGET-30-PALHVD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8127657-f161-4ea6-a9c2-fb688bad3cbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALHVD-10A (Blood Derived Normal), aliquot TARGET-30-PALHVD-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae564fd6-c374-4684-93aa-ac070fe071ae

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Splice Site 2, Silent 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 50/328 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNTNAP2 | c.3071C>A p.T1024K | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1415451310; called by muse, mutect2
- CPEB4 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1466318069, COSV54172592; called by muse, varscan2
- FAM83B | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV60922854, COSV60923230; called by mutect2, varscan2
- GABRE | c.1340G>C p.C447S | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV64819924; called by muse, mutect2
- MUC17 | c.5453C>A p.T1818K | Missense Mutation (SNP) | VAF 68/441 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV60291140; called by muse, varscan2
- MYO1F | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs191981941, COSV57796019; called by muse, mutect2, varscan2
- NSMCE1 | c.258+1G>C p.X86_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV63864381; called by muse, mutect2, varscan2
- PGLYRP3 | c.710T>G p.F237C | Missense Mutation (SNP) | VAF 126/924 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV51949492; called by muse, mutect2, varscan2
- SLC4A4 | c.170A>T p.K57M | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV52626304; called by muse, mutect2, varscan2
- SON | c.4799C>G p.A1600G | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV51660009; called by muse, mutect2, varscan2
- TTN | c.70547G>T p.R23516L (on ENST00000591111; = p.R16092L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | PolyPhen benign (0.401); catalogued as COSV100614979, COSV60113574; called by muse, mutect2, varscan2
- ARPC1A | c.64+4_64+7del p.X22_splice | Splice Site (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- ASAP1 | c.3269A>G p.E1090G | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- C1orf198 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 24/780 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.16); called by muse, mutect2
- CATSPER1 | c.964A>C p.T322P | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC150 | c.2353C>A p.L785M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, varscan2
- CLN8 | c.363C>T p.V121= | Silent (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- GPR68 | c.255C>T p.D85= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV53176582; called by muse, mutect2, varscan2
- TMEM167B | chr1:109100252 G>A | 3'Flank (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
